FM case AD16061 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/9331a194-c9c3-42c7-9f33-09644c0a0ca7

Female, 56.3 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the peritoneum; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
